Somatic mutation profile of tumor specimen TARGET-10-PARFDB-09A (aliquot TARGET-10-PARFDB-09A-01D) from TARGET case TARGET-10-PARFDB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.8 years (5,416 days).
Specimen TARGET-10-PARFDB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9f64f69-a67f-4d5e-98bd-829b833a46d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARFDB-10A (Blood Derived Normal), aliquot TARGET-10-PARFDB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7dfdec26-b8cb-4048-ad30-0113a4e8b1c3

The open-access MAF lists 19 somatic variants for this specimen: 8 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 6, Intron 2, 3'Flank 2, 5'UTR 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX15B | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as rs560167917; called by muse, mutect2, varscan2
- GPR6 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.166); catalogued as rs1486709700, COSV51571714; called by muse, mutect2, varscan2
- H2AC14 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV60799081; called by muse, mutect2, varscan2
- NRN1L | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1331023132, COSV100197846; called by muse, mutect2, varscan2
- SLC2A1 | c.805C>A p.R269S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as CM135625; called by muse, mutect2, varscan2
- SOX11 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.982); catalogued as rs866041767; called by muse, mutect2, varscan2
- ARID5B | c.695dup p.T233Dfs*11 | Frame Shift Ins (INS) | VAF 27/90 reads (30%) | called by mutect2, pindel, varscan2
- RSF1 | c.676_700del p.E226Rfs*20 | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | called by mutect2, pindel, varscan2
- ACAP2 | c.1950A>G p.L650= | Silent (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- ACOX3 | c.1561C>T p.L521= | Silent (SNP) | VAF 44/115 reads (38%) | called by muse, mutect2, varscan2
- JARID2 | c.1086C>T p.P362= | Silent (SNP) | VAF 45/125 reads (36%) | called by muse, mutect2, varscan2
- LTBP4 | c.3723C>T p.Y1241= (on ENST00000308370 / NM_001042544.1; = p.Y1204= on NM_003573.2) | Silent (SNP) | VAF 32/89 reads (36%) | called by muse, mutect2, varscan2
- RAB36 | c.807G>A p.S269= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as rs1272391256, COSV99572211; called by muse, mutect2, varscan2
- TEX13A | c.540G>A p.A180= | Silent (SNP) | VAF 23/28 reads (82%) | catalogued as rs938856840; called by muse, mutect2, varscan2
- GFRA2 | c.41-40C>T | Intron (SNP) | VAF 54/134 reads (40%) | catalogued as rs1248995640; called by muse, mutect2, varscan2
- MIR371A | chr19:53788069 G>A | 3'Flank (SNP) | VAF 8/18 reads (44%) | catalogued as rs146103406; called by muse, mutect2, varscan2
- NFIA | c.-86C>T | 5'UTR (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- NFX1 | c.3039+101T>C | Intron (SNP) | VAF 40/53 reads (75%) | catalogued as rs563681924; called by muse, mutect2, varscan2
- RN7SL176P | chr12:100158071 C>T | 3'Flank (SNP) | VAF 23/44 reads (52%) | catalogued as rs867439423; called by muse, mutect2, varscan2
